Surgical pathology report (de-identified scan), TCGA case TCGA-UZ-A9PJ, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma), tissue source site University of California San Francisco, specimen TCGA-UZ-A9PJ-01A (Primary Tumor).

[page 1 of 2]
SURGICAL PATHOLOGY REPORT

Patient Name: [REDACTED]
Med. Rec. #: [REDACTED] Visit #: [REDACTED]
DOB: [REDACTED] Sex: Male
Soc. Sec. #: [REDACTED] Location: [REDACTED]
Physician(s): [REDACTED]

Accession #: [REDACTED]
Service Date: [REDACTED]
Received: [REDACTED]
Client: [REDACTED]

FINAL PATHOLOGIC DIAGNOSIS

Right kidney, partial nephrectomy:

1. Renal cell carcinoma, papillary type, Fuhrman grade I, 2.5 cm; see comment.
2. No tumor at inked resection margin.

COMMENT:

Kidney Tumor Synoptic Comment

- Histologic type:** Renal cell carcinoma, papillary type 1.
- Grade:** Fuhrman grading for RCC: 1: Small nuclei, minute or absent nucleoli.
- Maximum tumor diameter:** The largest dimension of the tumor submitted to pathology was 2.5 cm, however, by report the tumor measured 3.1 cm.
- Site within kidney:** upper pole.
- Renal pelvis:** Not present.
- Ureter:** Not present.
- Renal sinus:** Not present.
- Hilar renal veins:** Not present.
- Intrarenal veins and lymphatics:** Normal, no tumor.
- Adrenal gland:** Not present.
- Capsule/perirenal fat:** Tumor does not penetrate capsule.
- Hilar lymph nodes (number positive/number of nodes):** No lymph nodes identified.
- Resection margins:** No tumor.
- Proximity to nearest margin:** 0.4 cm from kidney resection margin; >1cm from perinephric adipose tissue margin.
- Stage:** pT1aNXMX.

ICD-O-3
Carcinoma, papillary
renal cell 8260/3
Site @ Kidney NOS C64.9
01/30/14

Dr. [REDACTED] has reviewed the case and agrees with the diagnosis of papillary renal cell carcinoma.

Specimen(s) Received
A: Right renal mass

[page 2 of 2]
Clinical History

The patient is a [REDACTED] year-old male with a 3.1 cm right renal mass, who undergoes right partial nephrectomy.

Gross Description

The specimen is received fresh, labeled with the patient's name and medical record number, and consists of a partial nephrectomy specimen, which has pulled away, intraoperatively, from the main tumor mass. The specimen weighs 70 gm and consists of tan kidney parenchyma with a small amount of white-yellow, friable tumor. This portion of the specimen measures 1.9 x 1.3 x 2.3 cm. Additionally, there is a separate fragment of tumor of the same quality which measures approximately 2.5 cm in diameter. There is also detached perinephric fat, measuring 9.5 x 5.5 x 2.0 cm. It has a portion of capsule, which is indicated by the surgeon to have been adjacent to the tumor. This portion which was adjacent to the tumor is inked in green. The tumor is 0.4 cm from the deep inked resection margin which is inked black. Sectioning through the perinephric fat reveals no candidate lymph nodes. Sections are submitted as follows:

Cassette A1: Tumor approaching resection margin.

Cassettes A2-A3: Representative sections of tumor.

Cassette A4: Representative sections of capsule.

Cassette A5:

Uninvolved kidney.

Diagnosis based on gross and microscopic examinations. Final diagnosis made by attending pathologist following review of all pathology slides.

[REDACTED] Pathology Resident

[REDACTED] Pathologist
Electronically signed out on [REDACTED]

Source: NCI Genomic Data Commons file 7615c904-62e2-46d6-9d05-ea7f8f2394d9 (TCGA-UZ-A9PJ.66FB3AA3-97C6-40C6-8A73-D7FE4EFF5FCF.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).